Somatic mutation profile of tumor specimen ER-AE8R-TTM1-A (aliquot ER-AE8R-TTM1-A-1-0-D-A593-34) from EXCEPTIONAL_RESPONDERS case ER-AE8R, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell carcinoma; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 49.4 years (18,031 days).
Specimen ER-AE8R-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e86fc26f-5e79-4876-a01e-28882e5d22aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-AE8R-NT1-A (Solid Tissue Normal), aliquot ER-AE8R-NT1-A-1-0-D-A593-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/437ab2b8-7e97-4269-bda9-b49430de3ba5

The open-access MAF lists 38 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Intron 2, Frame Shift Del 2, Splice Site 1, 5'UTR 1, RNA 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.2158T>C p.Y720H | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1458690598; called by muse, mutect2
- ACAD11 | c.1522+1G>T p.X508_splice | Splice Site (SNP) | VAF 17/126 reads (13%) | catalogued as rs556222225; called by muse, mutect2, varscan2
- BRCA2 | c.5188A>T p.N1730Y | Missense Mutation (SNP) | VAF 42/467 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.782); catalogued as rs397507770, CM010168; ClinVar: not provided; called by muse, mutect2
- FGF14 | c.148G>T p.G50* | Nonsense Mutation (SNP) | VAF 8/95 reads (8%) | catalogued as COSV101086782; called by muse, mutect2
- MT1X | c.94+3G>T | Splice Region (SNP) | VAF 4/40 reads (10%) | catalogued as rs777695988; called by mutect2, varscan2
- PPP3R1 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 46/684 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV52249948; called by muse, mutect2
- ATAD2B | c.2225C>T p.S742L | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDC42BPB | c.1673C>A p.S558Y | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.211); called by muse, mutect2
- CSTF3 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCSTAMP | c.1167G>T p.M389I | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- DDX19B | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- DUSP1 | c.454A>G p.S152G | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- GPR155 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.496); called by muse, mutect2
- HSPA1L | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ICA1 | c.789A>T p.E263D | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.63); called by muse, mutect2
- METTL7B | c.230del p.L77Rfs*21 | Frame Shift Del (DEL) | VAF 10/110 reads (9%) | called by mutect2, pindel
- NNT | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- PTPN1 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFX2 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2
- SETDB1 | c.3762A>C p.R1254S (on ENST00000271640 / NM_001366417.1; = p.K1253N on NM_012432.4) | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2
- TLK2 | c.449T>G p.M150R | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.018); called by muse, mutect2
- TMEM176B | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- UBN2 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 34/496 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- USH2A | c.9326C>A p.T3109N | Missense Mutation (SNP) | VAF 13/247 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.022); called by muse, mutect2
- UTP4 | c.250A>G p.M84V | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF529 | c.1286_1290del p.K429Ifs*5 | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | called by mutect2, pindel
- ABCA13 | c.11766G>A p.Q3922= | Silent (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2
- ACTN4 | c.1521T>G p.S507= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- B3GNTL1 | c.570C>T p.S190= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as rs1166324308; called by muse, mutect2, varscan2
- CCDC110 | c.316C>T p.L106= | Silent (SNP) | VAF 16/165 reads (10%) | catalogued as COSV56870513; called by muse, mutect2, varscan2
- HBP1 | c.1290T>C p.S430= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as rs1363571286; called by muse, mutect2
- ROBO3 | c.381C>T p.R127= | Silent (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- SAV1 | c.174T>C p.N58= | Silent (SNP) | VAF 26/310 reads (8%) | called by muse, mutect2
- TRAFD1 | c.1212T>C p.I404= | Silent (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- FAF2 | c.-9G>A | 5'UTR (SNP) | VAF 14/115 reads (12%) | catalogued as rs1183926930; called by muse, mutect2, varscan2
- GFOD1 | c.253+16611C>A | Intron (SNP) | VAF 21/193 reads (11%) | catalogued as rs1484825897; called by muse, mutect2
- GFOD1 | c.253+16610T>A | Intron (SNP) | VAF 22/191 reads (12%) | catalogued as COSV64953098; called by muse, mutect2
- SLC22A20P | n.1421C>G | RNA (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
